Somatic mutation profile of tumor specimen TCGA-GN-A263-01A (aliquot TCGA-GN-A263-01A-11D-A196-08) from TCGA case TCGA-GN-A263, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 24.5 years (8,952 days).
Specimen TCGA-GN-A263-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5683c5ee-837b-4129-b465-21d393a7f19d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A263-10A (Blood Derived Normal), aliquot TCGA-GN-A263-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d92e9cff-f2d4-49f6-a94a-ba8d8b5c1408

The open-access MAF lists 518 somatic variants for this specimen: 351 protein-altering or splice-affecting, 163 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 319, Silent 163, Nonsense Mutation 13, Splice Site 9, Splice Region 6, Intron 2, In Frame Del 2, 5'Flank 1, Frame Shift Del 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 24/102 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 29/107 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IL7R | c.537+1G>A p.X179_splice | Splice Site (SNP) | VAF 15/44 reads (34%) | catalogued as rs777878144, CS0910535, COSV57408165, COSV57414477; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.3529C>T p.H1177Y | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV70027819; called by muse, mutect2, varscan2
- ABCA13 | c.5587C>T p.H1863Y | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV70027823; called by muse, mutect2, varscan2
- ABCB1 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55948973, COSV99712609; called by muse, mutect2, varscan2
- ABCB1 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55953442; called by muse, mutect2, varscan2
- ABHD11 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV56105636; called by muse, mutect2, varscan2
- AC008397.2 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53206678; called by muse, mutect2
- ACAA1 | c.574T>C p.F192L | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as COSV57173605; called by muse, mutect2, varscan2
- ACOT11 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV59347950; called by muse, mutect2
- ACSM2A | c.967C>T p.L323F (on ENST00000219054; = p.L244F on NM_001308169.2) | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV54591095; called by muse, mutect2, varscan2
- ACTA1 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64203247; called by muse, mutect2, varscan2
- ADAM18 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.192); catalogued as rs1451424338, COSV55846685; called by muse, mutect2, varscan2
- ADAM28 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56100104; called by muse, mutect2, varscan2
- ADAMTS12 | c.3483A>C p.E1161D | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV61261817; called by muse, mutect2, varscan2
- ADAMTS18 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770516167, COSV51399705; called by mutect2, varscan2
- ADCY3 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.662); catalogued as COSV53164396, COSV53168054; called by muse, mutect2, varscan2
- ADGRB1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV100030179, COSV60095791; called by muse, mutect2, varscan2
- ADGRL1 | c.2166G>A p.G722= (on ENST00000340736 / NM_001008701.3; = p.G717= on NM_014921.5) | Splice Region (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100529389; called by muse, mutect2
- ADGRL1 | c.2165G>A p.G722E (on ENST00000340736 / NM_001008701.3; = p.G717E on NM_014921.5) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100529390; called by muse, mutect2
- ADO | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV101060424; called by mutect2, varscan2
- AKAP3 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.087); catalogued as rs201140446, COSV57416155, COSV57422379; called by muse, mutect2, varscan2
- ALDH5A1 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62373393; called by muse, mutect2, varscan2
- ALLC | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV52994252; called by muse, mutect2, varscan2
- ALPK2 | c.1304C>A p.P435H | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV64492607; called by muse, mutect2, varscan2
- AMBRA1 | c.1262G>A p.R421Q (on ENST00000458649 / NM_001367468.1; = p.R331Q on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.608); catalogued as rs756008473, COSV54052224; called by muse, mutect2, varscan2
- ANGEL1 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs143581712, COSV51872814, COSV99200460; called by muse, varscan2
- ANK3 | c.10021G>A p.D3341N | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs765213109, COSV55055688, COSV55069067; called by muse, mutect2, varscan2
- AOAH | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218988618, COSV51740141; called by muse, mutect2, varscan2
- APEX1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV51657534; called by muse, mutect2, varscan2
- APOBR | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV60490256; called by muse, mutect2, varscan2
- AREG | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1219113338; called by muse, mutect2, varscan2
- ARHGEF40 | c.1358A>G p.E453G | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.073); catalogued as COSV53879937; called by muse, mutect2, varscan2
- ATP13A4 | c.2772G>A p.E924= | Splice Region (SNP) | VAF 11/101 reads (11%) | catalogued as COSV61317762, COSV61319639; called by muse, mutect2
- ATP13A4 | c.2674G>A p.E892K | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61319647; called by muse, mutect2, varscan2
- ATP2A3 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV59228618; called by muse, mutect2, varscan2
- BABAM2 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59622066; called by muse, mutect2, varscan2
- BCAS3 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV66773212; called by muse, mutect2, varscan2
- BICRAL | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as COSV58405082; called by muse, mutect2, varscan2
- BRINP2 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64177196; called by muse, mutect2, varscan2
- C8B | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.783); catalogued as rs867837249, COSV64776574; called by muse, mutect2, varscan2
- CACNG5 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.357); catalogued as COSV50055597; called by muse, mutect2, varscan2
- CAD | c.4688T>A p.F1563Y | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV53026326; called by mutect2, varscan2
- CAMK2B | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV51659930; called by muse, mutect2
- CAMSAP3 | c.509T>A p.L170H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50333410; called by muse, mutect2, varscan2
- CASD1 | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51970550; called by muse, mutect2
- CASP8 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV51848261; called by muse, mutect2, varscan2
- CASQ1 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as rs764105474, COSV63623241; called by muse, mutect2, varscan2
- CBFA2T3 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV51926436; called by muse, varscan2
- CBL | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 10/125 reads (8%) | catalogued as COSV50635561, COSV50650434; called by muse, mutect2
- CCDC170 | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.604); catalogued as COSV53340351; called by muse, mutect2, varscan2
- CCDC18 | c.3577G>A p.G1193R (on ENST00000343253 / NM_001306076.1; = p.G1194R on NM_206886.4) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758144419, COSV58143077; called by muse, mutect2, varscan2
- CCSER2 | c.2324C>T p.P775L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV56504824; called by muse, mutect2, varscan2
- CD48 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV63566485; called by muse, mutect2, varscan2
- CD96 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV51913310; called by muse, mutect2, varscan2
- CDC20B | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs753242954, COSV57051819; called by muse, mutect2, varscan2
- CDH6 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54066377; called by muse, mutect2, varscan2
- CENPE | c.3605G>A p.R1202K | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.695); catalogued as COSV54380488; called by muse, mutect2, varscan2
- CHI3L1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs773862311, COSV55137901; called by muse, mutect2, varscan2
- CHID1 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs1220696886, COSV60258787; called by muse, varscan2
- CHMP4C | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV51926202; called by muse, mutect2, varscan2
- CHRNA10 | c.1099C>G p.P367A | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV51704202; called by muse, mutect2, varscan2
- CHRNA10 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.91); PolyPhen benign (0.012); catalogued as COSV51704208; called by muse, mutect2, varscan2
- CIP2A | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV55418470; called by muse, mutect2, varscan2
- CLEC3A | c.317C>T p.S106F (on ENST00000651443; = p.S97F on NM_005752.6) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV55221285, COSV55224170; called by muse, mutect2, varscan2
- CNNM1 | c.1981C>T p.L661F | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765346829, COSV100763941, COSV63201376; called by muse, mutect2, varscan2
- CNTNAP4 | c.1801G>A p.G601R | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100273108, COSV56677521; called by muse, mutect2, varscan2
- COL1A1 | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.447); catalogued as COSV56803751, COSV56805886; called by muse, mutect2, varscan2
- COL28A1 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68081905; called by muse, mutect2, varscan2
- COL4A4 | c.4135C>T p.P1379S | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100306534; called by muse, mutect2, varscan2
- COL4A4 | c.3032G>A p.G1011E | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61631582; called by muse, mutect2, varscan2
- COL4A4 | c.1777G>A p.G593R | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs948847159, COSV61631585; called by muse, mutect2, varscan2
- COP1 | c.1973G>A p.G658E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58165189; called by muse, mutect2, varscan2
- CPN1 | c.485A>G p.N162S | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs750449248, COSV64942219; called by muse, mutect2, varscan2
- CPSF1 | c.2638G>A p.D880N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.439); catalogued as rs1470854849, COSV58233420; called by muse, varscan2
- CPXM2 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53860958; called by muse, mutect2, varscan2
- CRLF2 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.553); catalogued as COSV67493666; called by muse, mutect2, varscan2
- CSF2RA | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 68/304 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as rs147844397, COSV62624484, COSV62625721; called by muse, mutect2, varscan2
- CUTC | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.278); catalogued as COSV65081759; called by muse, mutect2, varscan2
- CWH43 | c.1822C>T p.H608Y | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV56938447; called by muse, mutect2, varscan2
- CXCL9 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.469); catalogued as COSV53578774; called by muse, mutect2, varscan2
- CYP1A2 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746644895, COSV59659632; called by muse, mutect2, varscan2
- CYP2C19 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as COSV64907608; called by muse, mutect2, varscan2
- CYP2J2 | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV64606051; called by muse, mutect2, varscan2
- CYP4F3 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967842174, COSV55409414; called by muse, mutect2, varscan2
- DAGLA | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57195634; called by muse, mutect2, varscan2
- DAXX | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV56468861; called by muse, mutect2, varscan2
- DCDC2 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 80/279 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs781230955, COSV65828654; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDI1 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs951750418, COSV56376481; called by muse, mutect2, varscan2
- DHCR7 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs565893436, CM010205, COSV62794728; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- DLL1 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV64537349; called by muse, mutect2, varscan2
- DMBT1 | c.7532C>T p.S2511L (on ENST00000338354 / NM_001377530.1; = p.S1754L on NM_004406.3) | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs1160076916, COSV57535215; called by muse, mutect2, varscan2
- DNAH11 | c.4622G>A p.R1541Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs780372134, COSV60942462; called by muse, mutect2, varscan2
- DNAH2 | c.8212C>T p.R2738* | Nonsense Mutation (SNP) | VAF 32/98 reads (33%) | catalogued as rs1332489191, COSV66717577; called by muse, mutect2, varscan2
- DNAH3 | c.10273C>T p.R3425C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750674790, COSV54518521; called by muse, mutect2, varscan2
- DNAH3 | c.8863G>A p.E2955K | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV54506197; called by muse, mutect2, varscan2
- DNAH5 | c.2869G>A p.E957K | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs762848961, COSV54206854; called by muse, varscan2
- DNAH5 | c.2744-1G>A p.X915_splice | Splice Site (SNP) | VAF 14/48 reads (29%) | catalogued as COSV54220956; called by muse, mutect2, varscan2
- DNAH7 | c.4018G>A p.D1340N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56762393, COSV56769357; called by muse, mutect2, varscan2
- DNAH9 | c.4211C>T p.T1404I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV99305139; called by muse, mutect2, varscan2
- DNTT | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as rs755818841, COSV64522745; called by muse, mutect2, varscan2
- DSC1 | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs868272055, COSV57144856; called by muse, mutect2, varscan2
- DSG1 | c.1283A>T p.N428I | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57134931; called by muse, mutect2, varscan2
- EDC4 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54645905; called by muse, mutect2, varscan2
- EEA1 | c.727G>T p.E243* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV100467403; called by muse, mutect2, varscan2
- EFCAB12 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs1304953606, COSV58176111; called by muse, mutect2, varscan2
- EGFLAM | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.342); catalogued as rs750559599, COSV59300471; called by muse, mutect2, varscan2
- ELOF1 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.543); catalogued as COSV52947655; called by muse, mutect2, varscan2
- EMILIN3 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); catalogued as COSV100182730, COSV60035996; called by muse, mutect2, varscan2
- ETV6 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs781494988, COSV67148589; called by muse, mutect2, varscan2
- F13A1 | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53552689, COSV99342657; called by muse, mutect2, varscan2
- F13A1 | c.988G>A p.G330R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99342660; called by muse, mutect2, varscan2
- FAM90A1 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as COSV56711820; called by muse, mutect2
- FAT2 | c.1600A>G p.R534G | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as COSV55818698; called by muse, mutect2, varscan2
- FBN2 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.051); catalogued as COSV52509538; called by muse, mutect2, varscan2
- FBXL2 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 49/152 reads (32%) | catalogued as COSV52138388; called by muse, mutect2, varscan2
- FBXL5 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV100377809; called by muse, mutect2, varscan2
- FBXL5 | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.782); catalogued as COSV100377810; called by muse, mutect2, varscan2
- FBXL8 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.017); catalogued as COSV99263463; called by muse, mutect2, varscan2
- FCHO1 | c.323A>C p.K108T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV53182199; called by muse, mutect2, varscan2
- FGL2 | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV50381080; called by muse, mutect2, varscan2
- FMN1 | c.3388G>A p.E1130K (on ENST00000616417 / NM_001277313.2; = p.E907K on NM_001103184.4) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV57922028; called by muse, mutect2, varscan2
- FPR3 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100200654; called by muse, mutect2, varscan2
- GABRA4 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs1475507683, COSV51926028; called by muse, mutect2, varscan2
- GALNT15 | c.404G>A p.W135* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV60215076, COSV60216772; called by muse, mutect2, varscan2
- GAREM1 | c.2344C>T p.P782S (on ENST00000269209 / NM_001242409.2; = p.P781S on NM_022751.3) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV52508666; called by muse, mutect2, varscan2
- GCSAML | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63577696; called by muse, mutect2, varscan2
- GDF3 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.403); catalogued as COSV61712333; called by muse, mutect2, varscan2
- GGCX | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52088113; called by muse, mutect2, varscan2
- GLRB | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1560962621, COSV52412316; called by muse, mutect2, varscan2
- GNAQ | c.1018G>C p.V340L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV54112332; called by muse, mutect2, varscan2
- GOLGA4 | c.2755G>A p.G919R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.054); catalogued as rs778570684, COSV62710454; called by muse, mutect2
- GOLGB1 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV61465302; called by muse, mutect2, varscan2
- GPHN | c.773G>A p.R258Q (on ENST00000315266 / NM_001377519.1; = p.R291Q on NM_020806.5) | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.921); catalogued as rs774716332, COSV59479165, COSV59484707; called by muse, mutect2, varscan2
- GPRIN3 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.081); catalogued as rs944996023, COSV60884751; called by muse, mutect2, varscan2
- GRIN2A | c.3965G>A p.G1322E | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.142); catalogued as COSV58021494; called by muse, mutect2, varscan2
- GRIN3A | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100701430, COSV62452343; called by muse, mutect2, varscan2
- GRM5 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs973046080, COSV59602884; called by muse, mutect2, varscan2
- GUSB | c.1844C>T p.P615L | Missense Mutation (SNP) | VAF 68/336 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100512561; called by muse, mutect2, varscan2
- GUSB | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 68/334 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100512562, COSV59220782; called by muse, mutect2, varscan2
- H6PD | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV66230935; called by muse, mutect2, varscan2
- HAP1 | c.897G>A p.L299= | Splice Region (SNP) | VAF 8/41 reads (20%) | catalogued as COSV57878364; called by muse, mutect2, varscan2
- HCAR3 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63673992; called by muse, mutect2, varscan2
- HDAC3 | c.477-1G>A p.X159_splice | Splice Site (SNP) | VAF 10/51 reads (20%) | catalogued as COSV59495766, COSV59498167; called by muse, mutect2, varscan2
- HECW2 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV53657764; called by muse, mutect2, varscan2
- HS3ST4 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 60/242 reads (25%) | catalogued as rs267604480, COSV58812934, COSV58826059; called by muse, mutect2, varscan2
- HSP90AA1 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as rs867800632, COSV53488412; called by muse, mutect2, varscan2
- HSPB7 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61307952; called by muse, mutect2, varscan2
- HYAL4 | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as rs370648762; called by muse, mutect2, varscan2
- IGHA2 | c.701C>T p.T234M | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs782717196; called by mutect2, varscan2
- INO80D | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as COSV68958769; called by muse, mutect2, varscan2
- INSYN2A | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54738122; called by muse, mutect2, varscan2
- IP6K3 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.404); catalogued as COSV53390034; called by muse, varscan2
- IQCH | c.2799+1G>A p.X933_splice | Splice Site (SNP) | VAF 15/61 reads (25%) | catalogued as COSV60052088; called by muse, mutect2, varscan2
- ITSN2 | c.3926T>C p.L1309P | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs532442838, COSV61946402; called by muse, mutect2, varscan2
- JAG1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs1193596340, COSV99652249; called by mutect2, varscan2
- JRKL | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.543); catalogued as COSV53593215; called by muse, mutect2, varscan2
- KALRN | c.1879C>T p.Q627* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV53761714; called by muse, mutect2, varscan2
- KCNK18 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.185); catalogued as rs1461272796, COSV57971628, COSV57973514; called by muse, mutect2, varscan2
- KCNT1 | c.2701G>A p.E901K (on ENST00000488444; = p.E920K on NM_020822.3) | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs866560094, COSV53700489; called by muse, mutect2, varscan2
- KCNT2 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.034); catalogued as COSV54076938; called by muse, mutect2, varscan2
- KEL | c.1320G>A p.M440I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs780238443, COSV62334685; called by muse, mutect2, varscan2
- KLHDC7A | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs780616009, COSV68769217; called by muse, mutect2, varscan2
- KLHL36 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as rs777399184, COSV50718766; called by muse, mutect2, varscan2
- KMT2D | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.293); catalogued as COSV56434717, COSV56481751; called by muse, mutect2, varscan2
- KRTAP22-1 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 51/166 reads (31%) | PolyPhen possibly damaging (0.69); catalogued as COSV58182200, COSV58182696; called by muse, mutect2, varscan2
- KSR2 | c.2018G>A p.G673E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265182078, COSV56671312; called by muse, mutect2, varscan2
- LAD1 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV66211988; called by muse, mutect2, varscan2
- LAMA3 | c.4316G>A p.R1439Q | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs752762070, COSV58067645; called by muse, mutect2, varscan2
- LAMA3 | c.6910G>A p.D2304N (on ENST00000313654 / NM_198129.4; = p.D695N on NM_000227.6) | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs1488366216, COSV52533978; called by muse, mutect2, varscan2
- LCT | c.3823G>A p.G1275R | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs540136979, COSV51546366; called by muse, mutect2, varscan2
- LGI1 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 26/104 reads (25%) | catalogued as COSV65057938; called by muse, mutect2, varscan2
- LPA | c.3145C>T p.P1049S | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV60301051; called by muse, mutect2, varscan2
- LRP1B | c.12596G>A p.G4199E | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs868543953, COSV67186838; called by muse, mutect2, varscan2
- LRP1B | c.1088G>A p.R363K | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1490600297, COSV101256412, COSV67212118; called by muse, mutect2, varscan2
- LRRC27 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59808589; called by muse, mutect2, varscan2
- MAP1A | c.6218C>T p.P2073L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as rs892856797, COSV55808142; called by mutect2, varscan2
- MAP3K12 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs758993212, COSV57232544; called by muse, mutect2, varscan2
- MAPK8IP1 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV53797622; called by muse, mutect2, varscan2
- MCHR2 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55999634; called by muse, mutect2, varscan2
- MEP1A | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57919647; called by muse, mutect2, varscan2
- MFSD12 | c.1249G>C p.G417R | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61535343; called by muse, mutect2, varscan2
- MGAT5 | c.596T>C p.L199S | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56096097; called by muse, mutect2, varscan2
- MLXIPL | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV57667997; called by muse, varscan2
- MMP16 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54162306; called by muse, mutect2, varscan2
- MPLKIP | c.446G>A p.W149* | Nonsense Mutation (SNP) | VAF 32/131 reads (24%) | catalogued as COSV59327989; called by muse, mutect2, varscan2
- MS4A13 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100981175, COSV65445654, COSV65445864; called by muse, mutect2, varscan2
- MTMR2 | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV100656632; called by muse, mutect2, varscan2
- MTMR2 | c.649A>T p.R217W | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100656633; called by muse, mutect2, varscan2
- MTMR7 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.201); catalogued as COSV51665464; called by muse, varscan2
- MUC16 | c.43063G>A p.D14355N | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated, low confidence (0.56); PolyPhen probably damaging (0.954); catalogued as rs776560450, COSV66691571, COSV66694479; called by muse, mutect2, varscan2
- MUC17 | c.10273G>A p.D3425N | Missense Mutation (SNP) | VAF 67/271 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV60287081; called by muse, mutect2, varscan2
- MUC17 | c.11567C>T p.S3856F | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs1478221727, COSV60287087; called by muse, mutect2, varscan2
- MYH1 | c.2537G>A p.S846N | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV56847334; called by muse, varscan2
- MYH4 | c.5786G>A p.R1929Q | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as rs778580924, COSV55117232; called by muse, mutect2, varscan2
- MYO9A | c.3012G>T p.K1004N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61858169; called by mutect2, varscan2
- MYOF | c.5303C>T p.P1768L | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100825202, COSV63703434; called by muse, mutect2, varscan2
- MYT1L | c.3484C>T p.R1162C | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.827); catalogued as rs772863694, COSV67701968; called by muse, mutect2, varscan2
- NAALAD2 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.236); catalogued as rs780072682, COSV58960498; called by muse, mutect2, varscan2
- NAALADL2 | c.2378G>A p.G793E | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV71984509; called by muse, mutect2, varscan2
- NALCN | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as COSV51916186; called by muse, mutect2, varscan2
- NAP1L2 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV65172451, COSV65172777; called by muse, mutect2, varscan2
- NBEAL1 | c.6391G>A p.D2131N | Missense Mutation (SNP) | VAF 128/514 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs527746341, COSV68915988; called by muse, mutect2, varscan2
- NCAN | c.3730T>G p.C1244G | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV53050399; called by muse, mutect2, varscan2
- NEK11 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as rs767453779, COSV63578843; called by muse, mutect2
- NFIA | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.986); catalogued as COSV64536857; called by muse, mutect2, varscan2
- NFKBIZ | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.123); catalogued as rs770051615, COSV58200163; called by muse, mutect2, varscan2
- NKIRAS2 | c.464G>C p.R155P | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV56917791; called by muse, mutect2, varscan2
- NLRP12 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs756104068, COSV60746725; called by muse, mutect2, varscan2
- NLRP5 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs766519785, COSV66764148; called by muse, mutect2, varscan2
- NPAS2 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100176020; called by muse, mutect2, varscan2
- NPAS2 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as COSV59564265; called by muse, mutect2, varscan2
- NPC1L1 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV56924590; called by muse, mutect2, varscan2
- NPHS2 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM141327, COSV62635145; called by muse, mutect2, varscan2
- OGDHL | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs749342327, COSV65102100; called by muse, mutect2, varscan2
- OR10G3 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 40/121 reads (33%) | catalogued as COSV57810124; called by muse, mutect2, varscan2
- OR13C5 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs267602070, COSV66164546; called by muse, mutect2, varscan2
- OR52M1 | c.669G>A p.M223I | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1371212709, COSV64171492; called by muse, mutect2, varscan2
- OR56B4 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs868420497, COSV57204206; called by muse, mutect2, varscan2
- OR5AK2 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV58804384; called by muse, mutect2, varscan2
- OR6N2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59411232; called by muse, mutect2
- OR8I2 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777929505, COSV56167693; called by muse, mutect2, varscan2
- OSBPL10 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as rs1395415925, COSV67338727; called by muse, mutect2, varscan2
- OSM | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV53161225; called by muse, mutect2, varscan2
- P2RX1 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV56653711; called by muse, mutect2, varscan2
- PADI6 | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV61884401; called by muse, mutect2, varscan2
- PARD3 | c.3915G>T p.E1305D | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV61054863; called by mutect2, varscan2
- PARVG | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.532); catalogued as COSV100796053; called by muse, mutect2, varscan2
- PCLO | c.14936G>A p.G4979E | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61631754; called by muse, mutect2, varscan2
- PCLO | c.8224G>A p.D2742N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV61631763; called by muse, mutect2, varscan2
- PDC | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV60854156; called by muse, varscan2
- PER2 | c.2776C>T p.P926S | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.355); catalogued as COSV54523237; called by muse, mutect2, varscan2
- PIK3C2B | c.1310+2T>G p.X437_splice | Splice Site (SNP) | VAF 23/109 reads (21%) | catalogued as COSV65803595; called by muse, mutect2, varscan2
- PIK3C2G | c.4373C>T p.T1458I (on ENST00000676171; = p.T1417I on NM_004570.5) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as COSV56807251; called by muse, varscan2
- PKD1L2 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV61414795; called by muse, mutect2, varscan2
- PKHD1 | c.11786-1G>A p.X3929_splice | Splice Site (SNP) | VAF 26/122 reads (21%) | catalogued as COSV100944129; called by muse, mutect2, varscan2
- PLA2G4E | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.144); catalogued as COSV68149967; called by muse, mutect2, varscan2
- PLB1 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.495); catalogued as COSV59823940; called by muse, mutect2, varscan2
- PLXNA4 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.442); catalogued as rs1189286697, COSV58121460, COSV58146496; called by muse, mutect2, varscan2
- POLR2M | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1454462029, COSV55210412; called by muse, mutect2, varscan2
- PPP3R2 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs867279328, COSV62453011; called by muse, mutect2, varscan2
- PRAME | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV67161476; called by muse, mutect2, varscan2
- PRAMEF12 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs539750824, COSV63215147; called by muse, mutect2, varscan2
- PRB3 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 69/238 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV54389468; called by muse, varscan2
- PRKX | c.824T>A p.I275N | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53323648; called by muse, mutect2, varscan2
- PRSS36 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51637037; called by muse, mutect2, varscan2
- PSENEN | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1299841235, COSV53074701; called by muse, mutect2, varscan2
- PSG9 | c.836G>A p.S279N | Missense Mutation (SNP) | VAF 80/327 reads (24%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.98); catalogued as rs1455796660, COSV52484747; called by muse, mutect2, varscan2
- PSTPIP2 | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 27/97 reads (28%) | catalogued as rs371122665; called by muse, mutect2, varscan2
- PTPRB | c.864C>T p.A288= | Splice Region (SNP) | VAF 13/60 reads (22%) | catalogued as rs1291236688, COSV54239287; called by muse, mutect2, varscan2
- PXDNL | c.2501C>T p.S834F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV62486403; called by muse, mutect2, varscan2
- R3HDM1 | c.2822C>T p.P941L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as COSV51524057, COSV99926576; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV54759650; called by muse, mutect2, varscan2
- RAB11FIP2 | c.1101del p.D368Ifs*19 | Frame Shift Del (DEL) | VAF 25/175 reads (14%) | catalogued as rs35192242, COSV62924876; called by pindel, varscan2
- REG3G | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55449254; called by muse, mutect2, varscan2
- RFC2 | c.713C>T p.S238F (on ENST00000055077 / NM_181471.3; = p.S204F on NM_002914.4) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50016111; called by muse, mutect2, varscan2
- RHBDF2 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV57420410; called by muse, mutect2, varscan2
- RHPN1 | c.1556G>T p.G519V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); catalogued as COSV56646528; called by mutect2, varscan2
- RIT2 | c.638G>A p.R213K | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58664455; called by muse, mutect2, varscan2
- RMDN3 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV99539926; called by muse, mutect2, varscan2
- RRAGD | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 59/271 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.466); catalogued as COSV100784520; called by muse, mutect2, varscan2
- RSF1 | c.3827G>A p.R1276Q | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as rs887469238, COSV57839232; called by muse, mutect2, varscan2
- RTL9 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT tolerated (0.89); PolyPhen benign (0.013); catalogued as COSV71825520; called by muse, mutect2, varscan2
- RUNX1T1 | c.1598G>A p.R533Q (on ENST00000265814 / NM_001198628.1; = p.R506Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779278771, COSV56138227; called by muse, mutect2, varscan2
- RUNX2 | c.1369C>T p.P457S (on ENST00000371438; = p.P435S on NM_001015051.3) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as rs746700872, COSV61840541; called by muse, mutect2, varscan2
- RYR1 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as COSV62095851; called by muse, mutect2, varscan2
- S1PR1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100541520; called by muse, mutect2, varscan2
- S1PR1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59514372; called by muse, mutect2, varscan2
- SCML2 | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV52620640; called by muse, mutect2, varscan2
- SCN11A | c.5035C>T p.R1679C | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs143537709, COSV56566354, COSV56579756; called by muse, mutect2, varscan2
- SCTR | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs371345970, COSV50027797; called by muse, mutect2, varscan2
- SEC23IP | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV64831379; called by muse, mutect2, varscan2
- SERPINA5 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs866630753, COSV61573556, COSV61574034; called by muse, mutect2, varscan2
- SERPINF1 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.958); catalogued as COSV54616129; called by muse, mutect2, varscan2
- SGSM1 | c.1423C>T p.L475F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV68510182; called by muse, mutect2, varscan2
- SH3RF1 | c.2429C>T p.P810L | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770591137, COSV52920417; called by muse, mutect2, varscan2
- SHKBP1 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV52539381; called by muse, mutect2, varscan2
- SLC16A8 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV57635297; called by muse, mutect2, varscan2
- SLC1A6 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV55669954; called by muse, varscan2
- SLC22A14 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV56197551; called by muse, mutect2, varscan2
- SLC22A9 | c.1461G>A p.M487I | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54167004; called by muse, mutect2, varscan2
- SLC25A31 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV55418994; called by muse, mutect2, varscan2
- SLC2A3 | c.235T>A p.F79I | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV50002271; called by muse, mutect2, varscan2
- SLC30A4 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV56005787; called by muse, mutect2, varscan2
- SLC6A13 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.428); catalogued as COSV58256933; called by muse, mutect2, varscan2
- SLCO2A1 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.312); catalogued as COSV100189512, COSV60485376; called by muse, mutect2, varscan2
- SPAG17 | c.3613G>A p.E1205K | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs781719346, COSV60455732; called by muse, mutect2, varscan2
- SPEG | c.5215A>C p.I1739L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.549); catalogued as COSV100403995; called by muse, mutect2, varscan2
- SPHKAP | c.1563G>A p.M521I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV60876786; called by muse, mutect2, varscan2
- SSUH2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.066); catalogued as COSV58029986; called by muse, mutect2, varscan2
- STARD13 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV55230242; called by muse, mutect2, varscan2
- STT3B | c.2177G>A p.G726E | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55502434; called by muse, mutect2
- STX6 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as COSV51111910; called by muse, mutect2, varscan2
- SYT2 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as COSV66141879; called by muse, mutect2, varscan2
- TACC2 | c.7838C>T p.S2613F (on ENST00000334433; = p.S691F on NM_006997.4) | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53277446; called by muse, mutect2, varscan2
- TAOK3 | c.549C>T p.Y183= | Splice Region (SNP) | VAF 19/84 reads (23%) | catalogued as COSV66825668; called by muse, mutect2, varscan2
- TAS2R41 | c.374G>A p.R125K | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.889); catalogued as rs773192241, COSV68765194; called by muse, mutect2, varscan2
- TCHHL1 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 62/287 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1281702301, COSV64285622; called by muse, mutect2, varscan2
- TCP11 | c.928C>T p.P310S (on ENST00000512012; = p.P248S on NM_018679.5) | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV55133510; called by muse, mutect2, varscan2
- TDRKH | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1004423330, COSV64316048; called by muse, mutect2, varscan2
- TECPR2 | c.2801C>T p.P934L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV100849909; called by muse, mutect2, varscan2
- TENM1 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 66/124 reads (53%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.007); catalogued as COSV64430901; called by muse, mutect2, varscan2
- THBS3 | c.2567C>T p.P856L | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV58363592; called by muse, mutect2, varscan2
- TIMM22 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV59098260; called by muse, mutect2, varscan2
- TJP3 | c.880A>T p.I294F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53662247; called by muse, mutect2, varscan2
- TLR8 | c.726C>A p.F242L (on ENST00000218032 / NM_138636.5; = p.F260L on NM_016610.4) | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV54317632; called by muse, mutect2, varscan2
- TLR8 | c.1855C>T p.R619C (on ENST00000218032 / NM_138636.5; = p.R637C on NM_016610.4) | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1178776493, COSV54317641, COSV99486832; called by muse, mutect2, varscan2
- TMCO5A | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.996); catalogued as rs756633826, COSV60464273; called by muse, mutect2, varscan2
- TMEM11 | c.397A>G p.K133E | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as COSV58313189; called by muse, mutect2, varscan2
- TMPRSS11A | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58358063; called by muse, mutect2, varscan2
- TMPRSS11B | c.687G>A p.K229= | Splice Region (SNP) | VAF 15/61 reads (25%) | catalogued as COSV60291749; called by muse, mutect2, varscan2
- TNRC6C | c.2557G>A p.V853M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV56944179; called by muse, mutect2, varscan2
- TOX4 | c.892-1G>A p.X298_splice | Splice Site (SNP) | VAF 21/113 reads (19%) | catalogued as COSV99398145; called by muse, mutect2, varscan2
- TOX4 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99398147; called by muse, mutect2, varscan2
- TPH2 | c.806-1G>A p.X269_splice | Splice Site (SNP) | VAF 30/130 reads (23%) | catalogued as rs1462187307, COSV61591753; called by muse, mutect2, varscan2
- TRAK1 | c.1610C>T p.S537F (on ENST00000327628 / NM_001349247.2; = p.S479F on NM_014965.5) | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.627); catalogued as COSV58258052; called by muse, mutect2, varscan2
- TRIM28 | c.1760C>T p.A587V | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs375189696; called by muse, mutect2, varscan2
- TRIM51 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.219); catalogued as COSV55266044; called by muse, mutect2, varscan2
- TRMT11 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as COSV57672771; called by muse, mutect2, varscan2
- TRPC7 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV61457307; called by muse, mutect2, varscan2
- TTC12 | c.1397G>A p.R466K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59097577; called by muse, mutect2, varscan2
- TTC22 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs780887864, COSV64881312; called by mutect2, varscan2
- TTN | c.96874C>G p.H32292D (on ENST00000591111; = p.H24868D on NM_003319.4) | Missense Mutation (SNP) | VAF 27/137 reads (20%) | PolyPhen benign (0.02); catalogued as COSV100598575, COSV60018311; called by muse, mutect2, varscan2
- TTN | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | PolyPhen benign (0.117); catalogued as COSV100589825, COSV60018397; called by muse, mutect2, varscan2
- UBASH3A | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV52312140; called by muse, mutect2, varscan2
- UNC5B | c.1811C>T p.S604L | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.345); catalogued as rs1470266228, COSV58976465; called by muse, mutect2, varscan2
- USP26 | c.1994C>T p.S665L | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs370040729, COSV63708582; called by muse, mutect2, varscan2
- USP6 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); catalogued as COSV51481218; called by muse, mutect2, varscan2
- VEGFA | c.547C>T p.P183S (on ENST00000523873 / NM_001171623.1; = p.P346S on NM_003376.6) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.694); catalogued as COSV57878379; called by muse, mutect2, varscan2
- VPS13D | c.11012C>T p.S3671L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV50635299; called by muse, mutect2, varscan2
- VWA3A | c.2062G>C p.D688H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV55390369; called by muse, mutect2
- WASF2 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.994); catalogued as COSV101420751; called by muse, mutect2, varscan2
- WBP11 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.227); catalogued as COSV53762782; called by muse, mutect2, varscan2
- WDR17 | c.3962C>T p.P1321L | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs766705869, COSV54572767; called by muse, mutect2, varscan2
- WIPI2 | c.1214G>A p.G405E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV56588686; called by muse, mutect2, varscan2
- XIRP2 | c.10G>A p.E4K (on ENST00000628543; = p.E179K on NM_152381.6) | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.012); catalogued as COSV54696650; called by muse, mutect2, varscan2
- ZFHX4 | c.2498G>A p.G833E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50727049; called by muse, mutect2
- ZFP30 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV63622575; called by muse, mutect2, varscan2
- ZFP42 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | catalogued as COSV58817253; called by muse, mutect2, varscan2
- ZKSCAN4 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV66023437; called by muse, mutect2, varscan2
- ZNF383 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61939086; called by muse, mutect2, varscan2
- ZNF652 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs774283118, COSV62946826; called by muse, mutect2, varscan2
- ZNF687 | c.2428C>T p.H810Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99649496; called by muse, mutect2, varscan2
- ZNF831 | c.2555C>T p.S852F | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100925984, COSV64039613; called by muse, mutect2, varscan2
- ZSCAN29 | c.1784G>A p.R595K | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.696); catalogued as COSV67822480; called by muse, mutect2, varscan2
- ZSWIM2 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); catalogued as COSV54575186; called by muse, mutect2, varscan2
- SLC35F3 | c.77-1G>A p.X26_splice (on ENST00000366617 / NM_001300845.1; = p.X95_splice on NM_173508.4) | Splice Site (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- TOPBP1 | c.719_721del p.H240del | In Frame Del (DEL) | VAF 34/146 reads (23%) | called by mutect2, pindel*, varscan2*
- ZNF624 | c.22_24del p.L8del | In Frame Del (DEL) | VAF 9/64 reads (14%) | called by mutect2, pindel, varscan2
- ABCA13 | c.834C>T p.S278= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as rs367866741, COSV70027815; called by muse, mutect2, varscan2
- ABHD17A | c.595C>T p.L199= (on ENST00000292577 / NM_001130111.2; = p.L250= on NM_031213.4) | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs768373575, COSV51750424; called by muse, mutect2, varscan2
- ADAMTS16 | c.2910C>T p.C970= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1430260287, COSV56987183; called by muse, mutect2, varscan2
- ADCY3 | c.120C>T p.V40= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99567998; called by muse, mutect2, varscan2
- ADO | c.168C>T p.S56= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs937485716, COSV101060423; called by muse, mutect2, varscan2
- AIFM3 | c.642G>A p.R214= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV58998467; called by muse, mutect2, varscan2
- ALPG | c.258C>T p.T86= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs753994708, COSV54965850; called by muse, mutect2, varscan2
- AMBRA1 | c.1263G>A p.R421= (on ENST00000458649 / NM_001367468.1; = p.R331= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as COSV100093330; called by muse, mutect2, varscan2
- AP2A1 | c.2262C>T p.V754= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV58241306; called by muse, mutect2, varscan2
- ARHGAP27 | c.1179C>T p.P393= (on ENST00000428638 / NM_001282290.1; = p.P52= on NM_199282.3) | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs760119685, COSV65357668; called by muse, mutect2, varscan2
- ARPC4 | c.33C>T p.A11= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as rs748081424, COSV55028476, COSV99809422; called by muse, mutect2, varscan2
- ASAH2 | c.198C>T p.R66= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs1362428657, COSV61483211; called by muse, mutect2, varscan2
- ASMT | c.225G>A p.V75= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs1211810647, COSV67109826; called by muse, mutect2, varscan2
- ASPHD1 | c.906G>A p.E302= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV58099120; called by muse, mutect2, varscan2
- ASTN1 | c.483C>T p.I161= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV56067627; called by muse, mutect2, varscan2
- AZU1 | c.687C>T p.F229= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV52140892; called by muse, varscan2
- BCL2L12 | c.51C>T p.F17= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as rs267605591, COSV55862539; called by muse, mutect2, varscan2
- CAMSAP3 | c.1419C>T p.L473= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV50333436; called by muse, mutect2, varscan2
- CARD10 | c.804G>A p.K268= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV52656130; called by muse, mutect2, varscan2
- CCDC170 | c.2127C>T p.G709= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs762737537, COSV53340367; called by muse, mutect2, varscan2
- CCP110 | c.591A>G p.E197= | Silent (SNP) | VAF 24/162 reads (15%) | catalogued as COSV66816908; called by muse, mutect2, varscan2
- CDH6 | c.750G>A p.G250= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs375949044; called by muse, mutect2, varscan2
- CDK5R1 | c.907C>T p.L303= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV100532020, COSV57830831; called by muse, mutect2, varscan2
- CFAP100 | c.477C>T p.F159= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs758898642, COSV61502935; called by muse, mutect2, varscan2
- CH25H | c.444G>A p.K148= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV64092301; called by muse, mutect2, varscan2
- CHML | c.1122C>T p.P374= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV59363874; called by muse, mutect2, varscan2
- CNGA4 | c.720G>A p.R240= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs746573667, COSV66005806; called by muse, mutect2, varscan2
- COL4A4 | c.4134C>T p.I1378= | Silent (SNP) | VAF 27/261 reads (10%) | catalogued as rs1559429872, COSV100306535; called by muse, mutect2, varscan2
- COL6A3 | c.7326G>A p.G2442= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV55087770; called by muse, mutect2, varscan2
- COL9A1 | c.1485G>A p.Q495= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV57882848; called by muse, mutect2, varscan2
- CX3CR1 | c.12C>T p.F4= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs369018912, COSV64195442; called by muse, mutect2, varscan2
- CYP4A11 | c.1401G>A p.L467= | Silent (SNP) | VAF 40/136 reads (29%) | catalogued as rs1295098461, COSV60223273, COSV60224996; called by muse, mutect2, varscan2
- DAB1 | c.915C>T p.I305= (on ENST00000371231; = p.I272= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV64692613; called by muse, mutect2, varscan2
- DCTN1 | c.3618C>T p.V1206= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV62620372; called by muse, mutect2
- DHRSX | c.381C>T p.I127= | Silent (SNP) | VAF 62/269 reads (23%) | catalogued as COSV58131465; called by muse, mutect2, varscan2
- DNAH3 | c.8862G>A p.E2954= | Silent (SNP) | VAF 40/201 reads (20%) | catalogued as COSV54528407; called by muse, mutect2, varscan2
- DNAH5 | c.5085G>A p.Q1695= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs1173217415, COSV54220932; called by muse, mutect2, varscan2
- DNAH8 | c.567C>T p.I189= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV59441926; called by muse, mutect2, varscan2
- DNMT3B | c.2058G>A p.E686= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as COSV52417886; called by muse, mutect2, varscan2
- DOCK11 | c.3069G>A p.V1023= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as rs764446657, COSV52237981; called by muse, mutect2, varscan2
- DOCK6 | c.3681C>T p.S1227= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs761102095, COSV53914066; called by muse, mutect2, varscan2
- DYSF | c.1536G>A p.L512= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV50305911; called by muse, varscan2
- EEA1 | c.726G>A p.L242= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV100467406; called by muse, mutect2, varscan2
- EEF1A2 | c.369C>T p.F123= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as rs375710105, COSV53205034; called by muse, mutect2, varscan2
- EFR3A | c.1026G>A p.L342= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV54456288; called by muse, mutect2, varscan2
- EFR3A | c.1713C>T p.L571= | Silent (SNP) | VAF 39/173 reads (23%) | catalogued as COSV54456305; called by muse, mutect2, varscan2
- ENTPD4 | c.699C>T p.V233= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV62268920; called by muse, mutect2, varscan2
- EYA2 | c.402C>T p.T134= | Silent (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2
- FOXP2 | c.1317C>T p.S439= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as COSV63485278; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1683C>T p.L561= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV58552810; called by muse, mutect2, varscan2
- FPR3 | c.351C>T p.T117= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100200655; called by muse, mutect2, varscan2
- GK2 | c.141C>T p.F47= | Silent (SNP) | VAF 36/143 reads (25%) | catalogued as rs1159418418, COSV62626667; called by muse, mutect2, varscan2
- GPR37L1 | c.745C>T p.L249= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV66162237; called by muse, mutect2, varscan2
- GRIN1 | c.444C>T p.S148= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV59294948; called by muse, mutect2, varscan2
- GRIN1 | c.630G>A p.E210= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1057522916, COSV59294968; ClinVar: likely benign; called by muse, mutect2, varscan2
- GTPBP1 | c.952C>T p.L318= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs754219556, COSV99323050; called by muse, mutect2, varscan2
- HEATR5A | c.5874C>T p.S1958= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV66340184; called by muse, mutect2, varscan2
- HTR5A | c.399G>A p.T133= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs774038878, COSV55282655, COSV55282788; called by muse, mutect2, varscan2
- IGHV3-13 | c.138C>T p.F46= | Silent (SNP) | VAF 26/179 reads (15%) | called by muse, mutect2, varscan2
- IL1RL2 | c.1440G>A p.G480= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV51814862; called by muse, mutect2, varscan2
- IL37 | c.324G>A p.P108= | Silent (SNP) | VAF 58/228 reads (25%) | catalogued as rs150018952, COSV54490836; called by muse, mutect2, varscan2
- INTS2 | c.486C>T p.F162= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV52152764; called by muse, mutect2, varscan2
- JAG1 | c.123C>T p.S41= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs761894056, COSV99652667; called by mutect2, varscan2
- JCAD | c.1260C>T p.F420= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as rs267602468, COSV64758899; called by muse, mutect2, varscan2
- KLKB1 | c.1842C>T p.V614= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as rs766760403, COSV52995374; called by muse, mutect2, varscan2
- KRTAP4-1 | c.228C>T p.P76= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, varscan2
- LMNB2 | c.240G>A p.E80= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV57587761; called by muse, mutect2, varscan2
- MAGI1 | c.2631C>T p.V877= (on ENST00000402939 / NM_001033057.2; = p.V905= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV58323951; called by muse, mutect2, varscan2
- MAP1A | c.2454C>T p.A818= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV55808134; called by muse, mutect2, varscan2
- MAP3K19 | c.3489C>T p.F1163= | Silent (SNP) | VAF 32/125 reads (26%) | catalogued as COSV59638416; called by muse, mutect2, varscan2
- MAPK4 | c.972A>C p.S324= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV68541918; called by muse, mutect2, varscan2
- MME | c.348C>T p.V116= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs1459481415, COSV64707149; called by muse, mutect2, varscan2
- MMP26 | c.720C>T p.L240= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV56172137; called by muse, mutect2, varscan2
- MORN1 | c.783C>T p.V261= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1322894274, COSV66002894; called by mutect2, varscan2
- MTUS2 | c.3774G>A p.K1258= (on ENST00000612955 / NM_001366650.1; = p.K237= on NM_015233.6) | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV66421047; called by muse, mutect2, varscan2
- MUC5AC | c.1578C>T p.T526= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV62253835; called by muse, mutect2, varscan2
- NAV2 | c.6435C>T p.S2145= (on ENST00000396087 / NM_001244963.2; = p.S2086= on NM_145117.5) | Silent (SNP) | VAF 43/147 reads (29%) | catalogued as COSV60656897; called by muse, mutect2, varscan2
- NEK10 | c.864G>A p.K288= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV58282791; called by mutect2, varscan2
- NELL1 | c.930C>T p.P310= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV54259911; called by muse, mutect2, varscan2
- NF1 | c.4437C>T p.F1479= (on ENST00000358273 / NM_001042492.3; = p.F1458= on NM_000267.3) | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as COSV100646532; called by muse, mutect2, varscan2
- NPHS1 | c.2301C>T p.P767= | Silent (SNP) | VAF 35/160 reads (22%) | catalogued as COSV62287568; called by muse, mutect2, varscan2
- NYAP2 | c.1083G>A p.T361= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs780896106, COSV56003534; called by muse, mutect2, varscan2
- OLFM4 | c.213C>T p.S71= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV54577073; called by muse, mutect2, varscan2
- OR2H1 | c.873G>A p.R291= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV65810587; called by muse, mutect2, varscan2
- OR2M5 | c.18G>A p.Q6= | Silent (SNP) | VAF 72/336 reads (21%) | catalogued as COSV63546143; called by muse, mutect2, varscan2
- OR4A5 | c.801C>T p.F267= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV60522343; called by muse, mutect2, varscan2
- OR51G1 | c.493C>T p.L165= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV58969054; called by muse, mutect2, varscan2
- OR5A1 | c.48C>T p.I16= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as COSV57376578; called by muse, mutect2, varscan2
- OR5M1 | c.255C>T p.F85= | Silent (SNP) | VAF 27/142 reads (19%) | catalogued as COSV73201948; called by muse, mutect2, varscan2
- OR8K5 | c.189C>T p.I63= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as COSV57888585; called by muse, mutect2, varscan2
- PADI1 | c.31C>T p.L11= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV64938289; called by muse, mutect2, varscan2
- PADI3 | c.1857C>T p.S619= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV64934457; called by muse, mutect2, varscan2
- PARVG | c.360G>A p.E120= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100796051; called by muse, mutect2, varscan2
- PCDH15 | c.2811G>A p.P937= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs1449039709, COSV57267597; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHB13 | c.753G>A p.Q251= | Silent (SNP) | VAF 61/169 reads (36%) | catalogued as COSV53396139; called by muse, mutect2, varscan2
- PCDHB13 | c.1323C>T p.I441= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV53395361; called by muse, mutect2, varscan2
- PLEC | c.13038C>T p.I4346= (on ENST00000322810 / NM_201380.4; = p.I4236= on NM_000445.5) | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs372573622; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- PLEKHN1 | c.378C>T p.F126= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV58021699; called by muse, mutect2, varscan2
- PLEKHN1 | c.639C>T p.P213= (on ENST00000379409; = p.P173= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs1470312645, COSV58021704; called by muse, mutect2, varscan2
- PM20D2 | c.120C>T p.A40= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV51530390; called by muse, mutect2, varscan2
- POU6F1 | c.1662G>A p.Q554= | Silent (SNP) | VAF 33/164 reads (20%) | catalogued as COSV61326616; called by muse, mutect2, varscan2
- PPBP | c.24C>T p.T8= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as COSV56019747; called by muse, mutect2, varscan2
- PPP4R3B | c.1305T>A p.V435= | Silent (SNP) | VAF 31/114 reads (27%) | catalogued as COSV55404188; called by muse, mutect2, varscan2
- PRR14 | c.858C>T p.I286= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs201116615; called by muse, mutect2, varscan2
- PTAFR | c.171G>A p.V57= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV59536680; called by muse, varscan2
- PXYLP1 | c.54C>T p.A18= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as COSV53890221; called by muse, mutect2, varscan2
- PXYLP1 | c.891C>T p.S297= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV53890233; called by muse, mutect2, varscan2
- RELN | c.2427C>T p.L809= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as COSV58999286; called by muse, mutect2, varscan2
- RGS11 | c.1131C>T p.T377= (on ENST00000397770 / NM_183337.3; = p.T356= on NM_003834.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV51452479; called by muse, mutect2, varscan2
- RGS22 | c.2259A>G p.P753= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV62661074; called by muse, mutect2, varscan2
- RMDN3 | c.216G>A p.G72= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs373934020; called by muse, mutect2, varscan2
- RNF123 | c.3360C>T p.N1120= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1345234653, COSV100246514; called by muse, mutect2
- RP1 | c.702C>T p.I234= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV55110856, COSV55111916; called by muse, mutect2, varscan2
- RRAGD | c.153G>A p.L51= | Silent (SNP) | VAF 60/270 reads (22%) | catalogued as COSV100784521; called by muse, mutect2, varscan2
- RRP12 | c.1005C>T p.T335= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV59667223; called by muse, mutect2, varscan2
- SCG2 | c.1093T>C p.L365= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV59539787; called by muse, mutect2, varscan2
- SCN10A | c.132G>A p.Q44= | Silent (SNP) | VAF 41/162 reads (25%) | catalogued as rs138739418, COSV71860793; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCNN1G | c.783C>T p.F261= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV55598525; called by muse, mutect2, varscan2
- SDCCAG8 | c.1287G>A p.K429= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV59406934, COSV59408338; called by muse, mutect2, varscan2
- SDK2 | c.3084G>A p.V1028= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV66185190; called by muse, mutect2, varscan2
- SEMA3G | c.1230C>T p.A410= | Silent (SNP) | VAF 31/125 reads (25%) | catalogued as rs757161299, COSV51595329; called by muse, mutect2, varscan2
- SERPINB12 | c.1110G>A p.R370= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV54032912; called by muse, varscan2
- SERPINF2 | c.657C>T p.F219= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV60664286; called by muse, mutect2, varscan2
- SERTM1 | c.144C>T p.F48= | Silent (SNP) | VAF 46/231 reads (20%) | catalogued as rs1251861251, COSV59376226; called by muse, mutect2, varscan2
- SFTPA1 | c.96C>T p.I32= | Silent (SNP) | VAF 31/144 reads (22%) | catalogued as rs148741681, COSV64866929; called by muse, mutect2, varscan2
- SH2D7 | c.324C>T p.I108= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV60926665; called by muse, mutect2, varscan2
- SHFL | c.681G>A p.K227= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs748736911, COSV53462068; called by muse, mutect2, varscan2
- SLC15A2 | c.1371G>A p.L457= | Silent (SNP) | VAF 42/181 reads (23%) | catalogued as rs755705534, COSV55197535; called by muse, mutect2, varscan2
- SLC4A4 | c.2982C>T p.F994= (on ENST00000264485 / NM_001098484.3; = p.F950= on NM_003759.4) | Silent (SNP) | VAF 38/163 reads (23%) | catalogued as COSV52622942; called by muse, mutect2, varscan2
- SLC6A18 | c.1257C>T p.F419= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as rs757382342, COSV57250970; called by muse, mutect2, varscan2
- SLC8A3 | c.1863G>A p.P621= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as rs376675749; called by muse, mutect2, varscan2
- SPATA21 | c.222G>A p.G74= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV59186585; called by muse, mutect2, varscan2
- SPEG | c.5214G>T p.R1738= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs921687303, COSV100403991, COSV56677354; called by muse, mutect2, varscan2
- SYNGR1 | c.276C>T p.F92= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV53368247; called by muse, mutect2, varscan2
- SYT9 | c.429G>A p.G143= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100608674, COSV59617624; called by muse, varscan2
- TAF4 | c.2896C>T p.L966= | Silent (SNP) | VAF 32/272 reads (12%) | catalogued as COSV53337213; called by muse, mutect2, varscan2
- TECPR2 | c.2802C>T p.P934= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs1304111478, COSV100849911, COSV100849932; called by muse, mutect2, varscan2
- THOC5 | c.1158C>T p.I386= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as COSV63798519; called by muse, mutect2, varscan2
- THSD7B | c.870G>A p.S290= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV55692984, COSV55693130; called by muse, mutect2, varscan2
- THUMPD2 | c.156C>T p.F52= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV53186895; called by muse, mutect2
- TMEM104 | c.1260C>T p.S420= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV59109134; called by muse, mutect2, varscan2
- TMEM63C | c.1956C>T p.I652= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV53603215; called by muse, mutect2, varscan2
- TOR3A | c.1173G>A p.R391= | Silent (SNP) | VAF 50/211 reads (24%) | catalogued as rs562737615, COSV61680057; called by muse, varscan2
- TP63 | c.531C>T p.F177= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV53204679; called by muse, mutect2, varscan2
- TRIML1 | c.618G>A p.E206= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV60194134; called by muse, mutect2, varscan2
- TRMT1L | c.609T>C p.V203= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as COSV62272217; called by muse, mutect2, varscan2
- TTC23 | c.1245G>A p.S415= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs782741576, COSV50441614; called by muse, mutect2, varscan2
- TTLL10 | c.1377G>A p.K459= (on ENST00000379289 / NM_001130045.2; = p.K386= on NM_153254.3) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV64959893; called by muse, mutect2, varscan2
- TULP1 | c.648G>A p.A216= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as rs766865255, COSV57692511; called by muse, mutect2, varscan2
- TULP4 | c.2826C>T p.T942= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV65574860; called by muse, mutect2, varscan2
- TXNDC2 | c.154C>T p.L52= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV60153182; called by muse, mutect2, varscan2
- UNC5D | c.1242C>T p.V414= | Silent (SNP) | VAF 58/248 reads (23%) | catalogued as COSV54790040, COSV54826119; called by muse, mutect2, varscan2
- USF3 | c.852G>A p.K284= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV57072181; called by muse, mutect2, varscan2
- WASF2 | c.1182C>T p.P394= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs200541363, COSV71005373; called by muse, mutect2, varscan2
- XIRP2 | c.1920A>G p.Q640= (on ENST00000628543; = p.Q815= on NM_152381.6) | Silent (SNP) | VAF 37/134 reads (28%) | catalogued as COSV54696668; called by muse, mutect2, varscan2
- ZBTB49 | c.1650C>T p.L550= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs746330269, COSV61924921; called by muse, mutect2, varscan2
- ZNF155 | c.351T>C p.S117= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV54206629; called by muse, mutect2
- ZNF439 | c.516C>T p.S172= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as COSV58309213; called by muse, mutect2, varscan2
- ZNF683 | c.78C>T p.S26= | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as COSV62874132; called by muse, mutect2, varscan2
- ZNF687 | c.2427C>T p.A809= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV99649492; called by muse, mutect2, varscan2
- ZNF710 | c.1365C>T p.L455= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV51562826; called by muse, mutect2, varscan2
- ZNF831 | c.3462C>T p.S1154= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV64039617; called by muse, mutect2, varscan2
- ZRANB3 | c.1638G>A p.R546= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV51500582; called by muse, mutect2, varscan2
- ANAPC11 | c.110-571C>T | Intron (SNP) | VAF 11/45 reads (24%) | catalogued as COSV58711183; called by muse, mutect2, varscan2
- ANKRD13C | chr1:70355065 G>A | 5'Flank (SNP) | VAF 7/44 reads (16%) | catalogued as COSV52031552; called by muse, mutect2, varscan2
- FOLH1B | n.1467G>A | RNA (SNP) | VAF 56/271 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.10361-4183G>A | Intron (SNP) | VAF 35/137 reads (26%) | catalogued as COSV59975887; called by muse, mutect2, varscan2
